Somatic mutation profile of tumor specimen MMRF_2300_1_BM_CD138pos (aliquot MMRF_2300_1_BM_CD138pos_T1_KHS5U_L11047) from MMRF case MMRF_2300, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.3 years (29,340 days).
Specimen MMRF_2300_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53506529-6bce-44ef-b5bc-ed2f41bbe381.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2300_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2300_1_PB_WBC_C2_KHS5U_L11048; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e58509cf-98d0-435b-9e1f-650f9ecd8c18

The open-access MAF lists 516 somatic variants for this specimen: 178 protein-altering or splice-affecting, 61 silent, 277 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, 3'UTR 146, Intron 70, Silent 61, 5'UTR 29, 5'Flank 13, 3'Flank 11, Nonsense Mutation 10, RNA 8, Splice Site 6, Splice Region 6, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.35C>A p.S12* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | hotspot (GDC flag); catalogued as rs141798398, CM072935, COSV58687783, COSV58689693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKHD1 | c.7612C>T p.L2538F | Missense Mutation (SNP) | VAF 115/469 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1378372748; called by muse, mutect2, varscan2
- APOB | c.9160G>C p.G3054R | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51922437; called by muse, mutect2, varscan2
- ARHGAP39 | c.3082G>C p.A1028P (on ENST00000276826 / NM_001308208.2; = p.A1059P on NM_025251.2) | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV52771639; called by muse, mutect2, varscan2
- ATP5MC2 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV58602463; called by muse, mutect2, varscan2
- BAX | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs760586942; called by muse, mutect2, varscan2
- BAZ2B | c.5783C>T p.S1928L | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV58596461, COSV58605145; called by muse, mutect2, varscan2
- BOP1 | c.989G>C p.W330S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376766975; called by muse, mutect2, varscan2
- CCDC30 | c.322G>C p.E108Q (on ENST00000340612; = p.E132Q on NM_001355227.2) | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); catalogued as rs989896429; called by muse, varscan2
- CREBBP | c.2905G>C p.D969H | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV52121887; called by muse, mutect2, varscan2
- DDX24 | c.2249C>T p.S750F | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52574485; called by muse, mutect2, varscan2
- DGAT1 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1335759761, COSV60047645; called by muse, varscan2
- DGAT2 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV57176971; called by muse, mutect2, varscan2
- DNAH8 | c.2897C>T p.A966V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs760404927; called by muse, mutect2, varscan2
- DOCK7 | c.6256G>A p.D2086N (on ENST00000635253 / NM_001367561.1; = p.D2055N on NM_033407.3) | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1374794957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2LI1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as CM155269, COSV53185371; called by muse, mutect2, varscan2
- EGR2 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs1411119456, COSV54346023, COSV54348081; called by muse, mutect2, varscan2
- EP400 | c.7849C>T p.R2617C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as rs767424945, COSV57767160; called by mutect2, varscan2
- EYA4 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as rs779172192, COSV62053244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FH | c.32C>G p.S11W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1226883651, COSV63819040, COSV63819277; called by muse, mutect2
- FMO2 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV52950347; called by muse, mutect2, varscan2
- GRIK1 | c.2720G>C p.R907T | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs932968557; called by muse, mutect2, varscan2
- HSPA9 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.782); catalogued as rs759861127; called by muse, mutect2, varscan2
- IGHG1 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs759790953; called by muse, mutect2, varscan2
- IGHJ6 | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 26/99 reads (26%) | PolyPhen benign (0); catalogued as rs376921777; called by muse, varscan2
- IGKV2-30 | c.181T>C p.F61L | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs754918992; called by muse, mutect2, varscan2
- IGLV3-1 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs563308501; called by muse, mutect2, varscan2
- INKA1 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1218405132; called by muse, varscan2
- KLHL32 | c.1495C>G p.L499V | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV100987302; called by muse, mutect2, varscan2
- LAMA2 | c.6666G>C p.L2222F | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.928); catalogued as COSV70356792; called by muse, mutect2, varscan2
- MAP9 | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs982065154; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by mutect2, varscan2
- MPHOSPH8 | c.2443C>T p.L815F | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1237663440; called by muse, mutect2, varscan2
- MRPL3 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs758185514; called by muse, mutect2, varscan2
- MRTFB | c.1077C>T p.F359= | Splice Region (SNP) | VAF 45/216 reads (21%) | catalogued as rs779093804, COSV57961151; called by muse, mutect2, varscan2
- MYO1C | c.142G>A p.V48M (on ENST00000648651 / NM_001080779.2; = p.V13M on NM_033375.5) | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs137888054; called by muse, mutect2, varscan2
- NAGLU | c.1457C>T p.S486F | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.424); catalogued as rs779707775; called by muse, mutect2, varscan2
- NCOR1 | c.1408-1G>C p.X470_splice | Splice Site (SNP) | VAF 14/39 reads (36%) | catalogued as COSV51978508; called by muse, varscan2
- NLRP7 | c.624C>G p.F208L | Missense Mutation (SNP) | VAF 68/287 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60174597; called by muse, mutect2, varscan2
- NTAN1 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as COSV52215987; called by muse, mutect2
- OPN4 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs772122696; called by muse, mutect2, varscan2
- OR10H3 | c.213G>C p.E71D | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV59944098; called by muse, mutect2, varscan2
- OR10K1 | c.398C>G p.S133* | Nonsense Mutation (SNP) | VAF 46/343 reads (13%) | catalogued as COSV99193832; called by muse, mutect2, varscan2
- PDE4A | c.2219C>T p.S740L (on ENST00000380702 / NM_001111307.2; = p.S501L on NM_006202.3) | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as rs764952909; called by muse, mutect2, varscan2
- PELI3 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.887); catalogued as rs753046516; called by muse, mutect2, varscan2
- PHACTR1 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs759030690, COSV60662175; called by muse, mutect2, varscan2
- PKN2 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as rs1438871655; called by muse, mutect2, varscan2
- PNMA8B | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.39); catalogued as rs1056186421; called by muse, mutect2, varscan2
- PREX1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as rs375685234; called by muse, mutect2, varscan2
- PRKG2 | c.1719C>G p.I573M | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs1417333846, COSV52325575, COSV52328292; called by muse, mutect2, varscan2
- PTBP1 | c.1039G>A p.E347K (on ENST00000349038 / NM_031991.4; = p.E373K on NM_002819.5) | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV62461799; called by muse, mutect2, varscan2
- PXDN | c.3202G>A p.A1068T | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157699250, COSV53245116; called by muse, mutect2, varscan2
- RASA2 | c.2408C>G p.S803C | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV53944241; called by muse, mutect2, varscan2
- RC3H2 | c.2708C>G p.S903* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100605713; called by muse, mutect2, varscan2
- REXO1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as COSV50074994; called by muse, mutect2, varscan2
- RIPK4 | c.2077G>A p.A693T (on ENST00000352483; = p.A645T on NM_020639.3) | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs188966621; called by muse, mutect2, varscan2
- ROM1 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as rs1181858709; called by muse, mutect2, varscan2
- RPF2 | c.157-3C>T | Splice Region (SNP) | VAF 16/70 reads (23%) | catalogued as rs774623616; called by muse, mutect2, varscan2
- SAFB | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 28/116 reads (24%) | catalogued as COSV99068552; called by muse, varscan2
- SEL1L2 | c.1435T>A p.W479R | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99532921; called by muse, mutect2, varscan2
- SEMG1 | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.581); catalogued as rs752819891; called by muse, mutect2, varscan2
- SPHKAP | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs775866234, COSV60871291, COSV60892119; called by muse, mutect2, varscan2
- SWT1 | c.1516C>G p.L506V | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100833437; called by muse, mutect2, varscan2
- SYNDIG1L | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1339667801; called by muse, varscan2
- TLR6 | c.2333G>C p.R778T | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV67935011; called by muse, mutect2, varscan2
- TMTC3 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs368224038; called by muse, mutect2, varscan2
- TRIM65 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs1567849232; called by muse, mutect2, varscan2
- TRMT2A | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 50/278 reads (18%) | catalogued as COSV52813778; called by muse, mutect2, varscan2
- WNT10A | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs750260671, CM1411728, COSV99297581; called by muse, mutect2, varscan2
- ZGRF1 | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as rs749190597; called by muse, varscan2
- ADAMTS7 | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2
- AMOTL2 | c.2119G>A p.E707K (on ENST00000422605; = p.E708K on NM_016201.4) | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CADPS | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- CATSPER1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC125 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 113/462 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CCDC194 | c.325-1G>A p.X109_splice | Splice Site (SNP) | VAF 31/136 reads (23%) | called by muse, mutect2, varscan2
- CCDC40 | c.2257G>C p.E753Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- CFAP65 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- CNKSR2 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, varscan2
- CNTRL | c.5347G>A p.E1783K | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- COL10A1 | c.1516C>A p.L506I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.125); called by mutect2, varscan2
- COP1 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- CTDSPL2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX15 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 60/307 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJB5 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- DPPA2 | c.861G>C p.K287N | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- DPPA3 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- DSCAM | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- FAM81A | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FGFR2 | c.2302-7C>G | Splice Region (SNP) | VAF 52/231 reads (23%) | called by muse, mutect2, varscan2
- FOXO4 | c.131C>A p.P44Q | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- FRG1KP | n.307G>A | Splice Region (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- FUBP3 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GSTT4 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- H3-5 | c.219G>C p.E73D | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- HEATR5A | c.3595G>C p.D1199H | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- HECW1 | c.4609A>G p.T1537A | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- HMCN2 | c.11485G>C p.E3829Q | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMGB1 | c.69_71del p.C23_R24delinsW | In Frame Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, varscan2
- HOXD9 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- IPCEF1 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ITGB4 | c.3317-1G>A p.X1106_splice | Splice Site (SNP) | VAF 75/286 reads (26%) | called by muse, mutect2, varscan2
- KCNJ3 | c.1069A>G p.S357G | Missense Mutation (SNP) | VAF 49/325 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIAA0753 | c.1090C>G p.L364V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KIAA1109 | c.14403C>G p.S4801R | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KMT2E | c.2197-4C>G | Splice Region (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- LRRC74A | c.93G>C p.E31D | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC9 | c.1080-1G>C p.X360_splice | Splice Site (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.1699A>G p.K567E | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by mutect2, varscan2
- LYST | c.8948-1G>C p.X2983_splice | Splice Site (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- MAG | c.1558_1559insGGCCG p.V520Gfs*9 | Frame Shift Ins (INS) | VAF 34/179 reads (19%) | called by mutect2, pindel, varscan2
- MAP4K1 | c.2450C>T p.S817L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MAST2 | c.1159C>G p.Q387E | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- METTL17 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIB1 | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MIB2 | c.2981C>G p.S994C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.639); called by muse, mutect2
- MICAL3 | c.2130G>C p.R710S | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- MINDY1 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- MLXIP | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2
- MSL3 | c.103-8C>T | Splice Region (SNP) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- MTMR4 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC6 | c.7317C>A p.D2439E | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); called by muse, varscan2
- MUS81 | c.1385G>C p.G462A | Missense Mutation (SNP) | VAF 62/312 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, varscan2
- MYO9A | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- NCOR1 | c.3037C>T p.Q1013* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- NCR2 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- NEK9 | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NFKBIE | c.625G>A p.D209N (on ENST00000275015; = p.D70N on NM_004556.3) | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- NHSL1 | c.3655G>C p.E1219Q | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NOP9 | c.1250C>A p.A417D | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.17); called by muse, mutect2
- NSUN2 | c.750G>C p.Q250H | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NUP43 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- OR5K4 | c.478G>C p.V160L | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- PASK | c.1164C>G p.F388L | Missense Mutation (SNP) | VAF 61/271 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PDE11A | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated, low confidence (0.41); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PHETA1 | c.288G>C p.E96D | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PLAA | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- PPP1R12B | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- PSMC5 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTHLH | c.216C>G p.I72M | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, varscan2
- PTPN1 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PUS7L | c.1729C>T p.H577Y | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RAPGEF6 | c.3649G>A p.E1217K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); called by muse, mutect2
- RBMX | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RDX | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RIC1 | c.1009G>T p.G337* | Nonsense Mutation (SNP) | VAF 19/106 reads (18%) | called by muse, varscan2
- SAAL1 | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, varscan2
- SDC4 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- SEC22C | c.508C>G p.P170A | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHPK | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- SLC17A8 | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- SLC27A3 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- SLC7A5 | c.801G>C p.M267I | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.114); called by muse, varscan2
- SMARCAD1 | c.1364T>C p.V455A | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, varscan2
- SPATA31E1 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- SPEN | c.8192C>T p.A2731V | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- STRN3 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- SV2C | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYMPK | c.2701-1G>C p.X901_splice | Splice Site (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- TACC3 | c.347G>C p.G116A | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- TDRD5 | c.2357C>T p.S786F | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TEC | c.300C>A p.D100E | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- TET3 | c.2407C>G p.L803V | Missense Mutation (SNP) | VAF 50/310 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- TEX10 | c.2664C>G p.I888M | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- TMEM236 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TMPRSS11E | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 61/306 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- TNRC18 | c.6176G>T p.G2059V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TRIM77 | c.1045G>C p.D349H | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRMT13 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TRPC5 | c.2582C>T p.S861L | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, varscan2
- UNC5D | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- UPF1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); called by muse, varscan2
- USP26 | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ZBED4 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 71/335 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ZC3H4 | c.3404G>A p.G1135E | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZMYM4 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZNF493 | c.1580A>C p.K527T | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4002G>A p.L1334= | Silent (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- ANGPTL6 | c.1392C>T p.L464= | Silent (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- ANKRD11 | c.651G>A p.A217= | Silent (SNP) | VAF 79/295 reads (27%) | catalogued as rs768461388, COSV56358503; called by muse, mutect2, varscan2
- ANKRD13C | c.1167C>T p.I389= | Silent (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- ANKS4B | c.297G>A p.Q99= | Silent (SNP) | VAF 56/204 reads (27%) | called by muse, varscan2
- ARMC9 | c.996G>A p.L332= | Silent (SNP) | VAF 45/189 reads (24%) | called by muse, mutect2, varscan2
- BBS2 | c.1353C>T p.V451= | Silent (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- C1QTNF4 | c.642C>T p.F214= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs899273211; called by muse, mutect2, varscan2
- C1orf167 | c.615G>A p.A205= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as rs569121321, COSV70596001; called by muse, mutect2, varscan2
- CCDC70 | c.540C>A p.L180= | Silent (SNP) | VAF 58/191 reads (30%) | called by muse, mutect2, varscan2
- CCR10 | c.648C>T p.F216= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs955181145, COSV99226245; called by muse, mutect2, varscan2
- CDC23 | c.1770C>T p.L590= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs769861375, COSV67509511; called by muse, mutect2, varscan2
- CHRD | c.75C>T p.R25= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs756193657; called by muse, mutect2, varscan2
- COG5 | c.303G>A p.Q101= | Silent (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- COL3A1 | c.1227G>C p.L409= | Silent (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- COL6A3 | c.4662C>T p.D1554= | Silent (SNP) | VAF 45/261 reads (17%) | catalogued as rs764225803, COSV55102308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDN | c.1104C>T p.L368= | Silent (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- DDX24 | c.1377G>A p.L459= | Silent (SNP) | VAF 30/197 reads (15%) | called by muse, varscan2
- DELE1 | c.1071C>T p.L357= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as rs140242859; called by muse, mutect2, varscan2
- DENND3 | c.738C>T p.F246= | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as rs531198735, COSV52801888; called by muse, mutect2, varscan2
- DNAAF1 | c.519G>A p.Q173= | Silent (SNP) | VAF 36/225 reads (16%) | catalogued as rs1365332109; called by muse, mutect2, varscan2
- ESYT1 | c.2514G>A p.S838= | Silent (SNP) | VAF 45/235 reads (19%) | catalogued as rs771690344; called by muse, mutect2, varscan2
- F8 | c.3699A>T p.I1233= | Silent (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- FLOT1 | c.1233C>T p.L411= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs1802471, COSV58357939; called by muse, mutect2, varscan2
- GPR39 | c.720C>T p.F240= | Silent (SNP) | VAF 50/220 reads (23%) | catalogued as rs1272655011; called by muse, mutect2, varscan2
- HAS1 | c.1590C>T p.S530= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs769655356, COSV55788233; called by muse, mutect2, varscan2
- IGLL5 | c.45G>A p.E15= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs544778929, COSV73248964, COSV73249402; called by muse, mutect2, varscan2
- IGLON5 | c.951G>C p.P317= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV54535021; called by muse, mutect2, varscan2
- ITGA9 | c.21G>A p.P7= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1488107532; called by muse, mutect2, varscan2
- MRPL10 | c.117G>A p.V39= | Silent (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- MTHFS | c.51G>A p.L17= | Silent (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- NFASC | c.3246C>T p.N1082= | Silent (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- NUP160 | c.1809C>T p.V603= | Silent (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2
- ODF2 | c.462C>T p.F154= (on ENST00000434106 / NM_153433.2; = p.F130= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 45/180 reads (25%) | catalogued as rs959281802; called by muse, mutect2, varscan2
- OR2M5 | c.864C>T p.L288= | Silent (SNP) | VAF 77/432 reads (18%) | catalogued as rs774417550; called by muse, mutect2, varscan2
- OSGIN2 | c.825G>A p.G275= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as COSV52407492; called by muse, mutect2, varscan2
- PDE6A | c.1227G>T p.G409= | Silent (SNP) | VAF 70/302 reads (23%) | called by muse, mutect2, varscan2
- PHLDB1 | c.3243G>A p.S1081= | Silent (SNP) | VAF 66/320 reads (21%) | catalogued as rs781835272, COSV100616344, COSV61878764; called by muse, mutect2, varscan2
- PKP1 | c.456G>A p.A152= | Silent (SNP) | VAF 60/124 reads (48%) | catalogued as rs759293051, COSV55823205; called by muse, mutect2, varscan2
- PRKD1 | c.126C>G p.V42= | Silent (SNP) | VAF 27/125 reads (22%) | called by muse, mutect2, varscan2
- PRPF40B | c.2037C>T p.F679= (on ENST00000380281; = p.F666= on NM_012272.3) | Silent (SNP) | VAF 55/241 reads (23%) | called by muse, mutect2, varscan2
- PTPRH | c.2367C>G p.L789= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs750866040; called by muse, mutect2, varscan2
- RARG | c.954C>G p.L318= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as COSV58432486; called by muse, mutect2, varscan2
- SAAL1 | c.667A>C p.R223= | Silent (SNP) | VAF 18/94 reads (19%) | called by muse, varscan2
- SLC39A13 | c.228C>T p.L76= | Silent (SNP) | VAF 53/268 reads (20%) | called by muse, mutect2, varscan2
- SLIT2 | c.1983C>T p.L661= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as COSV56586429; called by muse, mutect2, varscan2
- SOBP | c.1479G>A p.V493= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as rs764575517; called by muse, mutect2, varscan2
- SPATA3 | c.216T>C p.L72= | Silent (SNP) | VAF 111/482 reads (23%) | called by muse, mutect2, varscan2
- SPNS2 | c.1485C>T p.L495= | Silent (SNP) | VAF 77/340 reads (23%) | catalogued as rs1244837497; called by muse, mutect2, varscan2
- STXBP5 | c.2556G>A p.L852= (on ENST00000321680 / NM_001127715.2; = p.L816= on NM_139244.4) | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV51651895; called by muse, mutect2, varscan2
- TEX15 | c.6948A>T p.V2316= (on ENST00000256246; = p.V2699= on NM_001350162.2) | Silent (SNP) | VAF 43/202 reads (21%) | called by muse, mutect2, varscan2
- TMC5 | c.1233C>A p.S411= (on ENST00000396229 / NM_001105248.1; = p.S165= on NM_024780.5) | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as COSV54902707; called by muse, varscan2
- TNFRSF11A | c.1752C>T p.N584= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs1206865550; called by muse, mutect2, varscan2
- TRMT44 | c.1110C>T p.V370= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs193087059; called by mutect2, varscan2
- TSGA13 | c.90C>T p.V30= | Silent (SNP) | VAF 45/182 reads (25%) | called by muse, mutect2, varscan2
- USF3 | c.3750C>T p.I1250= | Silent (SNP) | VAF 41/197 reads (21%) | called by muse, mutect2, varscan2
- WFS1 | c.1698C>T p.F566= | Silent (SNP) | VAF 61/295 reads (21%) | catalogued as rs1466910093, CD134082; called by muse, mutect2, varscan2
- WNK1 | c.21G>A p.E7= | Silent (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- WNK1 | c.543G>A p.A181= | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- ZNF573 | c.1281C>A p.G427= (on ENST00000536220 / NM_001172692.1; = p.G369= on NM_152360.3) | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs1288558325; called by muse, mutect2, varscan2
- ZNF688 | c.33G>A p.P11= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs766371274; called by muse, mutect2, varscan2
- AAR2 | c.*148G>A | 3'UTR (SNP) | VAF 12/52 reads (23%) | called by mutect2, varscan2
- ABCC12 | c.*436C>T | 3'UTR (SNP) | VAF 17/78 reads (22%) | catalogued as rs879629053; called by muse, mutect2, varscan2
- ABI3BP | c.*842G>A | 3'UTR (SNP) | VAF 30/120 reads (25%) | called by muse, mutect2, varscan2
- ABTB1 | c.-42C>T | 5'UTR (SNP) | VAF 27/121 reads (22%) | catalogued as rs200194975, COSV99229578; called by muse, mutect2, varscan2
- AC011294.1 | n.1689G>A | RNA (SNP) | VAF 8/47 reads (17%) | catalogued as rs562856938; called by muse, mutect2, varscan2
- AC073254.1 | n.1132-1065C>T | Intron (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- AC116366.2 | c.-637-15688G>A | Intron (SNP) | VAF 5/40 reads (13%) | catalogued as rs1561597655; called by muse, mutect2, varscan2
- AC116366.2 | c.-637-15589G>C | Intron (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- AC235097.1 | n.148G>A | RNA (SNP) | VAF 23/59 reads (39%) | catalogued as rs1268222788; called by muse, mutect2, varscan2
- ACOX1 | c.109+18G>A | Intron (SNP) | VAF 33/153 reads (22%) | called by muse, mutect2, varscan2
- ADAM17 | c.*18C>T | 3'UTR (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.1588-91C>T | Intron (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- ADAMTS16 | c.1701+394C>G | Intron (SNP) | VAF 8/40 reads (20%) | called by mutect2, varscan2
- ADH6 | chr4:99203087 G>T | 3'Flank (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- AGBL2 | c.*289A>G | 3'UTR (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- AHSG | c.573+301C>G | Intron (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- AK7 | c.*773G>A | 3'UTR (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- AKR7A2 | c.591+89C>T | Intron (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- AL138930.1 | n.115+5866G>A | Intron (SNP) | VAF 28/136 reads (21%) | called by muse, mutect2, varscan2
- ALDH5A1 | c.438+102G>A | Intron (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2
- ANK1 | c.*1548C>T | 3'UTR (SNP) | VAF 32/199 reads (16%) | catalogued as COSV99224958; called by muse, mutect2, varscan2
- ANXA6 | c.*138C>T | 3'UTR (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- ARCN1 | c.*1947G>A | 3'UTR (SNP) | VAF 23/88 reads (26%) | called by muse, mutect2, varscan2
- ARHGEF6 | c.*2350G>A | 3'UTR (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- ARMC1 | c.*1779C>T | 3'UTR (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- ARMH3 | c.1782-41C>G | Intron (SNP) | VAF 21/93 reads (23%) | catalogued as rs1478592904; called by muse, mutect2, varscan2
- ASAP2 | c.*1569A>T | 3'UTR (SNP) | VAF 4/32 reads (13%) | catalogued as COSV53005749; called by muse, varscan2
- ATAD2 | c.*480C>T | 3'UTR (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- ATG16L1 | c.1204-1036C>T | Intron (SNP) | VAF 28/125 reads (22%) | called by muse, varscan2
- ATG2B | c.*3152C>T | 3'UTR (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2
- ATP8B3 | c.*287C>T | 3'UTR (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- B3GALT5-AS1 | n.698-45G>A | Intron (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- BBC3 | c.378-13C>T | Intron (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- BMP6 | c.*1052G>A | 3'UTR (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- BPTF | c.*846G>A | 3'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- BPTF | c.*848G>A | 3'UTR (SNP) | VAF 4/24 reads (17%) | catalogued as rs1555697649; called by muse, mutect2
- BUD13 | c.*269C>G | 3'UTR (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2
- C12orf66 | chr12:64186663 C>A | 3'Flank (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- C16orf87 | c.66+72C>T | Intron (SNP) | VAF 11/50 reads (22%) | catalogued as rs779888782; called by muse, mutect2, varscan2
- C1orf229 | n.1013G>T | RNA (SNP) | VAF 17/27 reads (63%) | called by muse, mutect2, varscan2
- C8orf34-AS1 | n.1872C>T | RNA (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2
- CACNA1D | c.5750-131C>G | Intron (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- CALN1 | c.*2061C>T | 3'UTR (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- CBFB | c.*1905A>T | 3'UTR (SNP) | VAF 11/75 reads (15%) | catalogued as rs941602932; called by muse, mutect2, varscan2
- CBL | c.*3379C>G | 3'UTR (SNP) | VAF 10/49 reads (20%) | called by mutect2, varscan2
- CBL | c.*5749G>C | 3'UTR (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- CBLN3 | c.*67G>A | 3'UTR (SNP) | VAF 36/157 reads (23%) | called by muse, mutect2, varscan2
- CCDC142 | c.-134G>C | 5'UTR (SNP) | VAF 33/176 reads (19%) | catalogued as COSV51778877; called by muse, mutect2, varscan2
- CCDC170 | c.*2063G>A | 3'UTR (SNP) | VAF 5/44 reads (11%) | catalogued as rs1425343961; called by muse, varscan2
- CCDC90B | c.*2748C>G | 3'UTR (SNP) | VAF 19/104 reads (18%) | called by muse, mutect2, varscan2
- CCL2 | c.*194G>A | 3'UTR (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- CD93 | c.*2762C>T | 3'UTR (SNP) | VAF 33/150 reads (22%) | catalogued as rs41282280; called by muse, mutect2, varscan2
- CFAP20DC | c.*447G>C | 3'UTR (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
- CFAP91 | c.201+70C>G | Intron (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
- CHCHD3 | c.170-11212C>T | Intron (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- CHD8 | c.*84C>T | 3'UTR (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- CILK1 | chr6:53065437 G>A | 5'Flank (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- CISH | c.*807G>A | 3'UTR (SNP) | VAF 46/227 reads (20%) | called by muse, mutect2, varscan2
- CLN8 | c.*3314G>A | 3'UTR (SNP) | VAF 52/196 reads (27%) | called by muse, mutect2, varscan2
- COG1 | c.2805+113C>T | Intron (SNP) | VAF 6/88 reads (7%) | catalogued as rs1476609003; called by muse, mutect2
- CORO6 | c.*205C>T | 3'UTR (SNP) | VAF 36/192 reads (19%) | catalogued as rs3744628; called by muse, mutect2, varscan2
- CRYBG3 | c.*112G>A | 3'UTR (SNP) | VAF 108/509 reads (21%) | catalogued as rs1400470469; called by muse, mutect2, varscan2
- CSNK2B | chr6:31665243 A>C | 5'Flank (SNP) | VAF 34/233 reads (15%) | called by muse, mutect2, varscan2
- DCAF12 | c.-233G>T | 5'UTR (SNP) | VAF 44/167 reads (26%) | called by muse, mutect2, varscan2
- DCC | c.*2334G>A | 3'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- DHCR24 | c.231+36G>A | Intron (SNP) | VAF 14/61 reads (23%) | catalogued as rs753674354; called by muse, mutect2, varscan2
- DICER1 | c.2651-10C>G | Intron (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- DOK1 | c.61-16C>T | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- DSG4 | c.*303G>C | 3'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- DUSP2 | c.*51_*52del | 3'UTR (DEL) | VAF 6/38 reads (16%) | called by pindel, varscan2
- DYNLRB2 | chr16:80540947 C>T | 5'Flank (SNP) | VAF 18/82 reads (22%) | catalogued as rs921404731; called by muse, mutect2
- E2F5 | c.*442G>C | 3'UTR (SNP) | VAF 71/293 reads (24%) | called by muse, mutect2, varscan2
- EIF3F | c.*5134C>T | 3'UTR (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
- EPG5 | c.*243G>C | 3'UTR (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- ERC1 | c.*2045T>G | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- ERC1 | c.*2288C>T | 3'UTR (SNP) | VAF 37/201 reads (18%) | called by muse, mutect2, varscan2
- ERC1 | c.*4429G>C | 3'UTR (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- ERC1 | c.*4571G>C | 3'UTR (SNP) | VAF 19/131 reads (15%) | catalogued as rs11061782; called by muse, mutect2, varscan2
- ERC1 | c.*4768G>A | 3'UTR (SNP) | VAF 47/346 reads (14%) | called by muse, varscan2
- ERVFRD-1 | c.*959C>G | 3'UTR (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- ETNK1 | c.-105C>T | 5'UTR (SNP) | VAF 17/79 reads (22%) | catalogued as rs545653162; called by muse, mutect2, varscan2
- EYS | c.1766+5553G>A | Intron (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- FAM172A | c.*285G>T | 3'UTR (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- FAT3 | c.*3617G>C | 3'UTR (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- FCRL1 | c.52+144C>T | Intron (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2
- FLNB | c.6367+103C>G | Intron (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2
- FOXJ3 | c.1352-153G>C | Intron (SNP) | VAF 43/198 reads (22%) | called by muse, mutect2, varscan2
- FOXP1 | c.181-18066G>A | Intron (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- FRK | c.*351C>T | 3'UTR (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- FRK | c.-241C>T | 5'UTR (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- FUCA1 | c.-1G>T | 5'UTR (SNP) | VAF 10/36 reads (28%) | catalogued as rs767034274; called by muse, mutect2, varscan2
- FUT10 | c.*1665C>T | 3'UTR (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- GCDH | c.-10C>T | 5'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- GLIS3 | c.*2415C>T | 3'UTR (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- GLP2R | c.*553G>A | 3'UTR (SNP) | VAF 25/111 reads (23%) | called by muse, mutect2, varscan2
- GLT8D1 | c.-269C>T | 5'UTR (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- GNPAT | c.-82G>A | 5'UTR (SNP) | VAF 47/166 reads (28%) | called by muse, mutect2, varscan2
- GPRC5C | c.1187-317G>T | Intron (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2
- GPRIN1 | c.*45C>A | 3'UTR (SNP) | VAF 51/221 reads (23%) | called by muse, mutect2, varscan2
- GPRIN3 | c.*891C>G | 3'UTR (SNP) | VAF 30/128 reads (23%) | called by muse, mutect2, varscan2
- GRB2 | c.*1781C>T | 3'UTR (SNP) | VAF 38/189 reads (20%) | called by muse, mutect2, varscan2
- GRB2 | c.*939C>A | 3'UTR (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- GRIA4 | c.487+44518G>T | Intron (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99235550; called by muse, mutect2
- H2AX | c.*504-90G>A | Intron (SNP) | VAF 41/276 reads (15%) | called by muse, mutect2, varscan2
- HBS1L | c.*1509C>T | 3'UTR (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- HCN1 | c.*1075C>G | 3'UTR (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100302049; called by muse, mutect2, varscan2
- HDAC2 | c.*3569C>G | 3'UTR (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- HECTD3 | c.1238+67G>C | Intron (SNP) | VAF 48/250 reads (19%) | called by muse, varscan2
- HELZ2 | chr20:63572629 G>C | 5'Flank (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- HMGB4 | c.-227G>T | 5'UTR (SNP) | VAF 22/135 reads (16%) | called by muse, mutect2, varscan2
- HMGCR | c.1369-24C>A | Intron (SNP) | VAF 25/109 reads (23%) | called by muse, mutect2, varscan2
- HOXA13 | c.*451C>T | 3'UTR (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- HOXB4 | c.*345G>C | 3'UTR (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- HPSE | c.*2391G>A | 3'UTR (SNP) | VAF 25/113 reads (22%) | catalogued as rs1448861490; called by muse, mutect2, varscan2
- HSPA12A | c.*2383G>T | 3'UTR (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- HTATSF1 | c.-69C>T | 5'UTR (SNP) | VAF 67/117 reads (57%) | called by muse, mutect2, varscan2
- HYPK | c.*206C>T | 3'UTR (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- ID2 | c.*7+41C>T | Intron (SNP) | VAF 50/262 reads (19%) | catalogued as rs527701869; called by muse, mutect2, varscan2
- IGKV2-29 | n.159A>G | RNA (SNP) | VAF 24/113 reads (21%) | called by muse, varscan2
- IGLV4-3 | chr22:22871503 del CAGTCTCGAATAGAGCTCTTGGAAGTCCCTCCAAC | 5'UTR (DEL) | VAF 17/114 reads (15%) | called by mutect2, pindel
- ILKAP | c.837-151G>C | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- INSRR | c.*209G>C | 3'UTR (SNP) | VAF 21/158 reads (13%) | called by muse, mutect2, varscan2
- IRF4 | c.*2164G>C | 3'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- IYD | c.*468C>A | 3'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- JADE1 | c.1503+98C>G | Intron (SNP) | VAF 75/259 reads (29%) | called by muse, mutect2, varscan2
- JUN | c.-232C>T | 5'UTR (SNP) | VAF 58/236 reads (25%) | called by muse, mutect2, varscan2
- KIAA0825 | c.*321G>C | 3'UTR (SNP) | VAF 13/78 reads (17%) | called by mutect2, varscan2
- KIAA1143 | c.*2326C>T | 3'UTR (SNP) | VAF 16/171 reads (9%) | called by muse, mutect2, varscan2
- KLF9 | c.*1536C>T | 3'UTR (SNP) | VAF 14/76 reads (18%) | catalogued as rs553945166; called by muse, mutect2, varscan2
- KRT15 | chr17:41518946 C>T | 5'Flank (SNP) | VAF 17/68 reads (25%) | catalogued as COSV99563199; called by muse, mutect2, varscan2
- KRT74 | c.*55C>T | 3'UTR (SNP) | VAF 9/40 reads (23%) | catalogued as rs920992918; called by muse, mutect2, varscan2
- LAP3 | c.-73C>T | 5'UTR (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99883932; called by muse, mutect2, varscan2
- LARS2 | c.*1290G>A | 3'UTR (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- LBX1 | c.-602G>A | 5'UTR (SNP) | VAF 24/119 reads (20%) | called by muse, mutect2, varscan2
- LIF | chr22:30240421 C>G | 3'Flank (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- LINC02694 | n.1250G>A | RNA (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- LONRF2 | c.*1000G>A | 3'UTR (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
- LRRC32 | c.*1543G>C | 3'UTR (SNP) | VAF 26/121 reads (21%) | called by muse, mutect2, varscan2
- LSM8 | c.201-451T>A | Intron (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- LY6K | c.218-385G>C | Intron (SNP) | VAF 90/365 reads (25%) | called by muse, mutect2, varscan2
- LYRM7 | c.*5380G>C | 3'UTR (SNP) | VAF 14/73 reads (19%) | catalogued as rs923578230; called by muse, mutect2, varscan2
- MALT1 | c.*4353C>T | 3'UTR (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- MIR1972-2 | chr16:70034252 G>A | 3'Flank (SNP) | VAF 39/179 reads (22%) | called by muse, mutect2, varscan2
- MMP16 | c.*8271G>C | 3'UTR (SNP) | VAF 26/122 reads (21%) | called by muse, mutect2, varscan2
- MPZL2 | c.-126G>A | 5'UTR (SNP) | VAF 35/115 reads (30%) | catalogued as COSV99635225; called by muse, mutect2, varscan2
- MRPS14 | c.*1374T>C | 3'UTR (SNP) | VAF 31/219 reads (14%) | called by muse, mutect2, varscan2
- MT1G | c.98-109C>G | Intron (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- MTX1 | chr1:155218219 G>A | 3'Flank (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- MYL9 | c.*537G>A | 3'UTR (SNP) | VAF 25/137 reads (18%) | called by muse, mutect2, varscan2
- MYNN | c.1483+200G>A | Intron (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- MZT2A | c.319+581G>A | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- NDUFA5 | c.*902G>A | 3'UTR (SNP) | VAF 30/157 reads (19%) | called by muse, mutect2, varscan2
- NDUFAF2 | chr5:61153090 G>C | 3'Flank (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- NDUFS1 | c.*589G>A | 3'UTR (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- NHSL2 | chrX:72132166 C>T | 5'Flank (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- NOTCH2 | c.*2782G>A | 3'UTR (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2, varscan2
- NTRK2 | c.1397-52421C>G | Intron (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- NUBP2 | c.*310G>C | 3'UTR (SNP) | VAF 23/129 reads (18%) | called by muse, mutect2, varscan2
- OLFML1 | c.*901C>G | 3'UTR (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- OR6Y1 | chr1:158546925 C>G | 3'Flank (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- OTUB2 | c.*504G>T | 3'UTR (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- P2RX7 | c.*427C>G | 3'UTR (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- P2RX7 | c.*592C>G | 3'UTR (SNP) | VAF 26/100 reads (26%) | called by muse, mutect2, varscan2
- PAX6 | c.141+165C>T | Intron (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- PAX7 | c.*923G>A | 3'UTR (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- PAX9 | c.*53C>T | 3'UTR (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- PCDHAC1 | c.*690C>A | 3'UTR (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- PDE10A | c.*5242G>A | 3'UTR (SNP) | VAF 16/75 reads (21%) | called by muse, mutect2, varscan2
- PDE7B | c.*98G>C | 3'UTR (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- PGAP1 | c.1952+365C>G | Intron (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- PGLYRP4 | c.*570C>G | 3'UTR (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- PGM5 | c.-312G>A | 5'UTR (SNP) | VAF 3/9 reads (33%) | catalogued as rs1387354666; called by muse, mutect2
- PIGK | c.986+196C>T | Intron (SNP) | VAF 13/67 reads (19%) | catalogued as rs1248875443; called by muse, mutect2, varscan2
- PIK3CD | c.*414G>A | 3'UTR (SNP) | VAF 75/270 reads (28%) | catalogued as rs1453067792; called by muse, mutect2, varscan2
- PLA2G4C | c.-165C>A | 5'UTR (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*836C>G | 3'UTR (SNP) | VAF 24/100 reads (24%) | catalogued as rs1014925391; called by muse, mutect2, varscan2
- POMGNT1 | c.*228A>T | 3'UTR (SNP) | VAF 41/217 reads (19%) | called by muse, mutect2, varscan2
- PPFIBP2 | c.487-4334G>A | Intron (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- PPP1R2 | c.*1290C>T | 3'UTR (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- PRDM16 | c.*4532G>A | 3'UTR (SNP) | VAF 6/63 reads (10%) | catalogued as rs922886406; called by muse, mutect2, varscan2
- PREB | c.-176G>A | 5'UTR (SNP) | VAF 64/274 reads (23%) | catalogued as rs372436206; called by muse, mutect2, varscan2
- PREX2 | c.*4177A>T | 3'UTR (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- PRMT5 | c.451-84G>C | Intron (SNP) | VAF 29/121 reads (24%) | called by muse, mutect2, varscan2
- PSG3 | c.*118G>A | 3'UTR (SNP) | VAF 20/128 reads (16%) | called by muse, mutect2, varscan2
- PSIP1 | c.*256G>A | 3'UTR (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
- PSMD5 | c.*1262_*1273del | 3'UTR (DEL) | VAF 14/85 reads (16%) | called by mutect2, pindel, varscan2
- PTPRD | c.*166A>G | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- PYGO1 | c.*52_*53del | 3'UTR (DEL) | VAF 53/323 reads (16%) | called by mutect2, pindel, varscan2
- RAB18 | c.*1701C>A | 3'UTR (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- RAB22A | c.*1219C>T | 3'UTR (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- RAB3B | c.*599G>A | 3'UTR (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- RALGDS | c.2211+78G>A | Intron (SNP) | VAF 29/131 reads (22%) | called by muse, mutect2, varscan2
- RAMP2 | chr17:42760477 C>A | 5'Flank (SNP) | VAF 45/247 reads (18%) | called by muse, mutect2, varscan2
- RAN | chr12:130876803 G>A | 3'Flank (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.65+8222C>T | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- RBFOX2 | c.*398G>C | 3'UTR (SNP) | VAF 29/182 reads (16%) | called by muse, mutect2, varscan2
- REM2 | c.728-20G>A | Intron (SNP) | VAF 34/131 reads (26%) | catalogued as rs1254134534; called by muse, mutect2, varscan2
- RIMS2 | c.698+52954A>G | Intron (SNP) | VAF 66/348 reads (19%) | catalogued as rs572378309, COSV51655429; called by mutect2, varscan2
- RNF135 | c.*543C>G | 3'UTR (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- RNF217 | c.*1216G>C | 3'UTR (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- RNF217 | c.*1679G>A | 3'UTR (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- ROBO1 | c.*753T>A | 3'UTR (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- ROBO2 | c.-172C>T | 5'UTR (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- RPL13 | c.246+102G>A | Intron (SNP) | VAF 43/177 reads (24%) | called by muse, mutect2, varscan2
- RTN4 | chr2:55050550 C>G | 5'Flank (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- SASH1 | c.*3457G>A | 3'UTR (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- SCAMP5 | c.294-119A>G | Intron (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- SCARB2 | c.1188-18C>T | Intron (SNP) | VAF 25/88 reads (28%) | called by muse, mutect2, varscan2
- SCN1A | c.*1249G>A | 3'UTR (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- SEC14L4 | c.*97G>A | 3'UTR (SNP) | VAF 23/120 reads (19%) | called by muse, mutect2
- SETD9 | chr5:56909321 C>T | 5'Flank (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- SF3A1 | c.*1045C>G | 3'UTR (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- SHBG | chr17:7628050 G>A | 5'Flank (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- SLC25A5 | chrX:119468103 C>T | 5'Flank (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2
- SLC26A9 | c.*1053C>T | 3'UTR (SNP) | VAF 24/181 reads (13%) | called by muse, mutect2, varscan2
- SLC2A5 | c.*126C>T | 3'UTR (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- SLC30A4 | c.*3049T>A | 3'UTR (SNP) | VAF 14/57 reads (25%) | called by muse, varscan2
- SLC30A4 | c.391+112A>G | Intron (SNP) | VAF 11/43 reads (26%) | catalogued as rs576715383; called by muse, mutect2, varscan2
- SLC36A1 | c.*2171C>T | 3'UTR (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- SLC38A2 | c.*1178G>A | 3'UTR (SNP) | VAF 12/75 reads (16%) | catalogued as COSV99873859; called by muse, mutect2, varscan2
- SLC5A7 | c.*1386G>C | 3'UTR (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- SLC8A1 | chr2:40112051 G>C | 3'Flank (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- SMAD1 | c.-109G>A | 5'UTR (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- SMARCC1 | c.3043+5836C>G | Intron (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- SNX20 | chr16:50666829 C>T | 3'Flank (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- SOCS2 | c.140-315C>T | Intron (SNP) | VAF 16/50 reads (32%) | catalogued as rs1193529162; called by muse, mutect2, varscan2
- SORBS3 | c.*659C>G | 3'UTR (SNP) | VAF 27/161 reads (17%) | called by muse, mutect2, varscan2
- SRGAP3 | c.*2827C>T | 3'UTR (SNP) | VAF 17/77 reads (22%) | catalogued as rs1559826036; called by muse, mutect2, varscan2
- STAG3L5P | n.345+2063G>A | Intron (SNP) | VAF 28/138 reads (20%) | called by muse, mutect2, varscan2
- STK32B | c.*1807C>G | 3'UTR (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- STXBP4 | c.945+359G>A | Intron (SNP) | VAF 157/764 reads (21%) | catalogued as COSV54840886; called by muse, mutect2, varscan2
- STXBP5L | c.*479G>A | 3'UTR (SNP) | VAF 60/226 reads (27%) | called by muse, mutect2, varscan2
- SYNCRIP | chr6:85611021 A>G | 3'Flank (SNP) | VAF 44/219 reads (20%) | called by muse, mutect2, varscan2
- SYNJ2BP | c.-116C>G | 5'UTR (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2
- SYTL5 | c.*1090C>A | 3'UTR (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- TACC2 | c.*210C>T | 3'UTR (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2
- TARS3 | c.*792G>C | 3'UTR (SNP) | VAF 8/53 reads (15%) | catalogued as rs914555452; called by muse, mutect2, varscan2
- TEX261 | c.373-46C>G | Intron (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2
- THAP2 | c.*808G>A | 3'UTR (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- TLNRD1 | c.-855G>A | 5'UTR (SNP) | VAF 9/34 reads (26%) | catalogued as rs1357800253; called by muse, mutect2, varscan2
- TMCO1 | chr1:165769152 C>T | 5'Flank (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- TMEM132A | c.2028+91C>G | Intron (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- TMEM74 | c.*394G>A | 3'UTR (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- TMEM81 | c.-91C>T | 5'UTR (SNP) | VAF 82/187 reads (44%) | called by muse, mutect2, varscan2
- TMPRSS11F | c.*182C>T | 3'UTR (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2, varscan2
- TPRG1L | c.*1145G>A | 3'UTR (SNP) | VAF 22/110 reads (20%) | called by muse, mutect2, varscan2
- TRIM77BP | n.319G>A | RNA (SNP) | VAF 21/104 reads (20%) | called by muse, mutect2, varscan2
- TSC22D3 | c.-271G>C | 5'UTR (SNP) | VAF 47/119 reads (39%) | called by muse, mutect2, varscan2
- TTC19 | c.*249G>A | 3'UTR (SNP) | VAF 19/106 reads (18%) | called by muse, mutect2, varscan2
- TTC41P | n.3094C>G | RNA (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- UBE2J1 | c.-107C>T | 5'UTR (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- UBR4 | c.7214-357G>C | Intron (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- URB1 | c.*1896C>T | 3'UTR (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- USH2A | c.*2703T>C | 3'UTR (SNP) | VAF 11/72 reads (15%) | catalogued as rs1436175588; called by muse, mutect2, varscan2
- USP47 | c.*2113C>T | 3'UTR (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- VPS37B | c.*1358C>T | 3'UTR (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2, varscan2
- WDR27 | c.457-90C>T | Intron (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- WDR6 | c.-10G>A | 5'UTR (SNP) | VAF 30/89 reads (34%) | called by muse, mutect2, varscan2
- WNK1 | c.-908C>T | 5'UTR (SNP) | VAF 75/292 reads (26%) | called by muse, mutect2, varscan2
- WWC1 | c.-356G>A | 5'UTR (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2
- XIRP2 | c.*803G>A | 3'UTR (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- XPO4 | c.*4294C>T | 3'UTR (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- YIF1B | c.58+160G>C | Intron (SNP) | VAF 32/104 reads (31%) | called by mutect2, varscan2
- ZBTB46 | c.*1414G>C | 3'UTR (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- ZC3H14 | c.1280-1637G>C | Intron (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- ZC3H18 | c.2470-97G>C | Intron (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2
- ZFYVE21 | c.359-26C>G | Intron (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- ZMAT4 | c.*175C>G | 3'UTR (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99910457; called by mutect2, varscan2
- ZNF197 | c.391-157C>G | Intron (SNP) | VAF 17/70 reads (24%) | catalogued as rs528576370; called by muse, mutect2
- ZNF215 | c.*27C>T | 3'UTR (SNP) | VAF 52/254 reads (20%) | catalogued as rs200546603; called by muse, mutect2, varscan2
- ZNF22 | chr10:44999738 C>T | 5'Flank (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- ZNF398 | c.*2702G>A | 3'UTR (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- ZNF44 | c.*789C>G | 3'UTR (SNP) | VAF 26/121 reads (21%) | called by muse, mutect2, varscan2
- ZNF451 | c.*499G>C | 3'UTR (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- ZNF568 | c.-185-12C>G | Intron (SNP) | VAF 5/38 reads (13%) | catalogued as COSV61740545; called by muse, mutect2
- ZNF76 | c.625+98G>A | Intron (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- ZSCAN2 | c.407-4227C>T | Intron (SNP) | VAF 74/330 reads (22%) | called by muse, mutect2, varscan2
